Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3881, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3881-01A (Primary Tumor).

Diagnosis

This is an advanced mucinous carcinoma (G3) with infiltration of the bordering fatty connective tissue (p T 3) and an inflammatory connection to the uterus.

Otherwise the uterus condition is normal relative to the patient's age and there are free lymph nodes (p N 0).

Tumor classification:

ICDO-DA-M

G3, p T 3, L1, V1, p N 0 (0/30).

Source: NCI Genomic Data Commons file 41b0c42a-7901-4343-a21b-8a5b3243d3be (TCGA-AG-3881.38D06531-7A33-4A2C-9169-B760CEAD35B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).